Somatic mutation profile of tumor specimen MBCProject_3154_T2_WES (aliquot MBCProject_3154_T2_WES_1) from CMI case MBCProject_3154, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 33.0 years (12,063 days).
Specimen MBCProject_3154_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23b203ed-aa9d-48f6-889a-c3bac26a2766.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3154_SALIVA (Saliva), aliquot MBCProject_3154_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/729f64cf-093a-4bbd-ba91-38b42a2f9a87

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLC1 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV61416756; called by muse, mutect2
- LILRB5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100300458; called by muse, mutect2, varscan2
- MPP6 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs769291787; called by muse, mutect2
- MTMR4 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 64/786 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as rs775203610, COSV60203997; called by muse, mutect2
- OR52A1 | c.787_789del p.F263del | In Frame Del (DEL) | VAF 18/142 reads (13%) | catalogued as rs766997566; called by pindel, varscan2
- STK25 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.017); catalogued as rs746631738; called by muse, mutect2
- AL662899.2 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 36/381 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); called by muse, mutect2
- CARMIL2 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); called by muse, mutect2
- STXBP5 | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); called by muse, mutect2
- ALG10 | c.1086T>C p.V362= | Silent (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- APOBEC2 | c.618G>A p.E206= | Silent (SNP) | VAF 8/171 reads (5%) | catalogued as rs1369775565; called by muse, mutect2
- GPRC5C | c.639C>T p.V213= (on ENST00000652232; = p.V168= on NM_018653.4) | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as rs762354061; called by muse, mutect2
- MRGPRD | c.444G>A p.L148= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- OTOP2 | c.1104C>T p.D368= | Silent (SNP) | VAF 134/237 reads (57%) | catalogued as rs768778471, COSV58882465; called by muse, mutect2, varscan2
- PACS2 | c.2391G>A p.T797= | Silent (SNP) | VAF 31/217 reads (14%) | catalogued as rs1295485158; called by muse, mutect2, varscan2
- LIPC | c.88+4714_88+4715dup | Intron (INS) | VAF 38/362 reads (10%) | called by mutect2, pindel, varscan2
- MTHFD2L | c.143+1782G>C | Intron (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
